Surgical pathology report (de-identified scan), TCGA case TCGA-AY-4070, project TCGA-COAD (Colon Adenocarcinoma), tissue source site UNC, specimen TCGA-AY-4070-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REVISED REPORT

Surgical Pathology Report

* Amended *

Diagnosis:

A: Implant, uterine, biopsy

- Nodule of benign smooth muscle consistent with leiomyoma,
no tumor seen.

B: Colon, right, hemicolectomy

Tumor Histologic Type: adenocarcinoma

Histologic Grade: poorly differentiated

Depth of Invasion: through muscularis propria into
pericolic adipose tissue.

Lymphatic (Small Vessel) Invasion: present

Venous (Large Vessel) Invasion: present

Perineural space invasion: present

Margins:

Proximal margin: free of tumor

Distal margin: free of tumor

[page 2 of 5]
Circumferential (radial) margin: involved with tumor (block B11)

Regional lymph nodes:

Total number with metastasis: 5

Total number examined: 15

AJCC PATHOLOGIC TNM STAGE: at least pT3, cannot exclude pT4
pN2 pMx

Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Additional pathologic findings: The appendix shows fibrous obliteration.

The attached portion of small bowel shows no pathologic abnormality.

Intraoperative Consult Diagnosis:

A frozen section was requested by [REDACTED].

FSA1: "Uterine implant", biopsy

- Benign fibromuscular tissue, no carcinoma seen.

Clinical History:

a clinical diagnosis of colon cancer, now undergoes right hemicolectomy.

Gross Description:

Received are two appropriately labeled containers.

Container A is additionally labeled "uterine implant." It contains a 0.4 x 0.3 x 0.3 cm white and red soft tissue fragment; block FSA1, NTR.

Container B is additionally labeled "right colon."

Specimen fixation: formalin

[page 3 of 5]
Parts of bowel received: terminal ileum, cecum, proximal ascending colon, appendix

Specimen length: terminal ileum, 11 cm; cecum/colon, 36 cm; appendix, 7 cm

Orientation: By anatomic landmarks. Inking: radial margin/blue.

Tumor location: cecum

Gross appearance of tumor: The tumor on the mucosal surface is present as an indurated depression with a rolled border. Cross sectioning reveals additional rubbery firm white solid tissue with focal yellow necrosis. This is present in the pericecal adipose tissue/subserosa. The tumor mass here has an infiltrative border with a stellate pattern of extension, including to the radial margin.

Tumor dimensions: 6.5 x 3.0 x 3.0 cm

Circumferential growth: 40%

Gross depth of invasion: Tumor invades through the muscularis propria into the subserosa/pericecal adipose tissue.

Gross evidence of perforation through visceral peritoneum: Tumor is at least very close to the peritoneum.

Luminal obstruction: not appreciable

Bowel circumference at tumor site: 7 cm

Gross distance of tumor from margins: 11 cm to terminal ileum margin, 32 cm to colon margin, radial margin is at least within 1 mm, may be positive

Lymph nodes: per block summary

Other remarkable findings: Within the subserosa directly below the primary tumor mass, there are multiple foci of yellow/white tumor nodules distending circumferential fibrous tissue.

[page 4 of 5]
These may
represent lymph nodes completely replaced by tumor,
vascular invasion, and/or exuberant desmoplastic response
to subserosal
tumor deposits.

Tissue submitted for special investigation: Tumor and
normal tissue to Tissue procurement.

Digital photograph taken:

Block Summary:

Inking: radial margin is blue

B1,B2 - terminal ileum margin of resection, en face
B3-B5 - colonic margin of resection, en face
B6-B8 - full thickness cross section of tumor, from mucosa
to positive
radial margin
B9-B11 - full thickness cross section of tumor, from mucosa
to positive
radial margin
B12 - additional view of subserosal invasion
B13-B15 - additional views of grossly positive radial
margin
B16,B17 - subserosal tumor deposits with circumferential
fibrous tissue
B18,B19 - tumor, transition to normal mucosa
B20 - normal colon, distal from tumor
B21 - normal terminal ileum, distal from tumor
B22 - appendix, cross section of tip and en face sections
of base and middle

B23 - two lymph node candidates, one bisected and inked
blue
B24 - tumor replaced lymph node versus vascular invasion
B25 - two lymph node candidates, larger bisected and inked
blue
B26 - two lymph node candidates
B27 - three lymph node candidates
B28 - two lymph node candidates
B29 - three very small lymph node candidates
B30 - two lymph node candidates
B31-B40 - perivascular adipose tissue

[page 5 of 5]
Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed by [REDACTED]

Source: NCI Genomic Data Commons file d6f4cdd7-553f-4cbe-88dd-0eb5fb81b1b4 (TCGA-AY-4070.A8C762BA-73AF-4802-82B4-22FD376AF0A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).